HCMI case HCM-BROD-0051-C64 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/46b1210c-4042-4c67-9e68-06e960f201f2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2012; Vital status: Alive.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; ICD-10 code: C78.0; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: metastasis; Age at diagnosis: 2.6 years (941 days); Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; COG renal stage: Stage IV; Sites of involvement: Lung, NOS / Lymph Node, Regional; Wilms tumor histologic subtype: Favorable.
   Pathology details: Anaplasia present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Dactinomycin + Vincristine; Treatment intent type: Neoadjuvant; Regimen or line of therapy: VAC; Days to treatment start: 61 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin Hydrochloride + Etoposide + Vincristine; Treatment intent type: Neoadjuvant; Days to treatment start: 61 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant; Days to treatment start: 122 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DD4A.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dactinomycin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DD4A.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Doxorubicin; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DD4A.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Etoposide; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DD4A.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Vincristine; Treatment intent type: Maintenance Therapy; Initial disease status: Progressive Disease; Regimen or line of therapy: DD4A.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Follow-up contact recording only the day: day 641.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 17.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0051-C64-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-BROD-0051-C64-06B-01-S1-HE: Section location: Top; Percent tumor cells: 96; Percent tumor nuclei: 94; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 4; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0051-C64-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 25; Percent tumor nuclei: 45; Percent normal cells: 65; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0051-C64-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Samples HCM-BROD-0051-C64-85A, HCM-BROD-0051-C64-85B (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 18.
- Sample HCM-BROD-0051-C64-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 23.
